Somatic mutation profile of tumor specimen TCGA-AB-2830-03B (aliquot TCGA-AB-2830-03B-01W-0728-08) from TCGA case TCGA-AB-2830, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.1 years (23,404 days).
Specimen TCGA-AB-2830-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e1d4bc5-3b13-49f0-8e27-2db9f94493f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2830-11B (Solid Tissue Normal), aliquot TCGA-AB-2830-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de69dc95-0cbd-451b-84a5-eaf829d6efae

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- THRB | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 71/304 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs121918697, CD910557, CM930706, COSV54980104; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SH3BP4 | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778737481, COSV60643723; called by muse, mutect2, varscan2
- TASOR2 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746590270, COSV60167193; called by muse, varscan2
- TBC1D8B | c.1005T>A p.N335K | Missense Mutation (SNP) | VAF 68/432 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV52178327; called by muse, mutect2, varscan2
- ATP11C | c.3336C>T p.S1112= | Silent (SNP) | VAF 75/317 reads (24%) | catalogued as rs1320845986, COSV59559000, COSV59563097; called by muse, mutect2, varscan2
- DDN | c.669G>A p.R223= | Silent (SNP) | VAF 3/57 reads (5%) | catalogued as COSV100305069; called by muse, mutect2
